CCDI case PBBHMI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4c437e5c-0271-475b-9293-6895f339d078

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,918 days).

Biospecimens (4 samples)
- Samples 0D920I, 0D94VB (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D94VD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D95OK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
